Somatic mutation profile of tumor specimen TCGA-DY-A0XA-01A (aliquot TCGA-DY-A0XA-01A-11D-A152-10) from TCGA case TCGA-DY-A0XA, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.8 years (21,115 days).
Specimen TCGA-DY-A0XA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00642f72-dc36-4ac9-9859-959dce7d4f72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DY-A0XA-10A (Blood Derived Normal), aliquot TCGA-DY-A0XA-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2c66d43-1ccf-4b27-ae3c-2a27ebd22d63

The open-access MAF lists 143 somatic variants for this specimen: 114 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 26, Nonsense Mutation 7, Splice Region 2, RNA 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.344G>C p.R115P | Missense Mutation (SNP) | VAF 26/61 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.312); catalogued as CM1312620, COSV55890007, COSV55898949, COSV55991501; called by muse, mutect2, varscan2
- TP53 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 15/25 reads (60%) | hotspot (GDC flag); catalogued as CM971503, COSV52676850, COSV52715987, COSV52740951; called by muse, mutect2, varscan2
- ABHD16A | c.1546+2T>A p.X516_splice | Splice Site (SNP) | VAF 15/55 reads (27%) | catalogued as COSV65451515; called by muse, mutect2, varscan2
- ABL1 | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as COSV59327630, COSV59331373; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1660G>A p.V554I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs769048034, COSV54997999; called by muse, mutect2, varscan2
- ADAR | c.1814C>G p.S605* | Nonsense Mutation (SNP) | VAF 51/112 reads (46%) | catalogued as COSV52713296; called by muse, mutect2, varscan2
- AFF2 | c.3712C>T p.R1238C | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1263514787, COSV53981655, COSV99664742; called by muse, mutect2, varscan2
- AGBL1 | c.1937A>T p.Y646F | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66852892; called by muse, mutect2, varscan2
- ALG10B | c.628A>C p.K210Q | Missense Mutation (SNP) | VAF 95/233 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.717); catalogued as COSV58142737; called by muse, mutect2, varscan2
- APC | c.2510C>A p.S837* | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | catalogued as rs79512956, CD011083, CD084036, CM014886, COSV57338611, COSV57345932; ClinVar: other; called by muse, mutect2, varscan2
- APC | c.3922A>T p.K1308* | Nonsense Mutation (SNP) | VAF 42/133 reads (32%) | catalogued as COSV57320906, COSV57398650; called by muse, mutect2, varscan2
- ASPSCR1 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs558896726, COSV60727816; called by muse, mutect2, varscan2
- ATOH1 | c.104C>A p.P35Q | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.308); catalogued as rs772119264, COSV60037550; called by muse, mutect2, varscan2
- ATP6V1G3 | c.47A>G p.K16R | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55278622; called by muse, varscan2
- BTN1A1 | c.1204G>T p.G402W | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55067000; called by muse, mutect2, varscan2
- CACNA1I | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60803623; called by muse, mutect2, varscan2
- CASP5 | c.917A>T p.K306I | Missense Mutation (SNP) | VAF 119/339 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99508049; called by muse, mutect2, varscan2
- CCNB3 | c.292C>A p.H98N | Missense Mutation (SNP) | VAF 174/346 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52071229; called by muse, varscan2
- CDK5RAP2 | c.2155G>A p.D719N | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.521); catalogued as COSV62572982; called by muse, mutect2, varscan2
- CELSR1 | c.7573A>T p.T2525S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as COSV53085975; called by muse, mutect2, varscan2
- CNTN5 | c.1474A>T p.I492F | Missense Mutation (SNP) | VAF 97/279 reads (35%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.832); catalogued as COSV54292984; called by muse, mutect2, varscan2
- CORO7 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs778533107, COSV52028791; called by muse, mutect2, varscan2
- DCAF4L2 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV60477323; called by muse, mutect2, varscan2
- DCDC1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as COSV60837333; called by muse, mutect2, varscan2
- DENND4A | c.4456A>G p.I1486V | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV71265449; called by muse, mutect2
- DGKB | c.1327G>C p.V443L | Missense Mutation (SNP) | VAF 48/342 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); catalogued as COSV51769714; called by muse, mutect2, varscan2
- DISP1 | c.4268G>A p.S1423N | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); catalogued as COSV99452102; called by muse, mutect2, varscan2
- DISP1 | c.4269C>G p.S1423R | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV52656594; called by muse, mutect2, varscan2
- DMRT3 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs141821476, COSV51909084, COSV99505697; called by muse, mutect2, varscan2
- DNAH3 | c.1261C>T p.H421Y | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99770234; called by muse, mutect2, varscan2
- DPY19L4 | c.237G>T p.W79C | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV68962484; called by muse, mutect2, varscan2
- DSCC1 | c.351G>A p.E117= | Splice Region (SNP) | VAF 64/212 reads (30%) | catalogued as COSV58086686; called by muse, mutect2, varscan2
- ESCO1 | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as COSV52518908; called by muse, mutect2, varscan2
- FRAS1 | c.1937A>G p.Y646C | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs751444327, COSV53598130; called by muse, mutect2, varscan2
- GABBR2 | c.394G>T p.G132* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as COSV52296919; called by muse, mutect2, varscan2
- GABRG2 | c.1268G>A p.R423H (on ENST00000361925 / NM_001375343.1; = p.R383H on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs528036202, COSV62716272, COSV62721034; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- GCN1 | c.2369C>G p.A790G | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV56105341; called by muse, mutect2, varscan2
- GJA8 | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as COSV53788216; called by muse, mutect2, varscan2
- GPAT2 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1199406895, COSV64003252; called by muse, mutect2, varscan2
- GPR108 | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV51184344; called by muse, mutect2, varscan2
- GPR158 | c.3163G>A p.A1055T | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV66267186; called by muse, mutect2, varscan2
- GRIA2 | c.1694G>T p.S565I | Missense Mutation (SNP) | VAF 223/498 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV52385723; called by muse, mutect2, varscan2
- GRM6 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs554079886, COSV51437117; called by muse, mutect2, varscan2
- HEPH | c.2297G>T p.G766V (on ENST00000343002; = p.G499V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/203 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1424594591, COSV57960892, COSV57966713; called by muse, mutect2, varscan2
- HRNR | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 82/207 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV64255874; called by muse, mutect2, varscan2
- HTR1E | c.633C>G p.S211R | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.261); catalogued as COSV59507304; called by muse, mutect2, varscan2
- HYDIN | c.7633C>T p.R2545W | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as rs373825456; called by muse, mutect2, varscan2
- ILDR2 | c.1822C>G p.R608G | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV99614376; called by muse, mutect2, varscan2
- ITGA3 | c.2209C>T p.Q737* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV50307136; called by muse, mutect2, varscan2
- IZUMO4 | c.620C>T p.P207L (on ENST00000395301 / NM_001039846.2; = p.P189L on NM_001031735.3) | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as COSV61425925; called by muse, mutect2, varscan2
- JHY | c.1682A>G p.D561G | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV99913697; called by muse, mutect2, varscan2
- KATNB1 | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143811277; called by muse, mutect2, varscan2
- KCNG2 | c.1079A>C p.Y360S | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60267074; called by muse, mutect2, varscan2
- KCNT2 | c.370T>A p.Y124N | Missense Mutation (SNP) | VAF 89/240 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV54070208; called by muse, mutect2, varscan2
- KHDC4 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.919); catalogued as COSV64164743; called by muse, varscan2
- KIF15 | c.3240A>T p.K1080N | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV58159294; called by muse, mutect2, varscan2
- KMT2E | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99996920; called by muse, mutect2, varscan2
- LMCD1 | c.428C>G p.P143R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99337825; called by muse, mutect2, varscan2
- LNX2 | c.1769G>C p.G590A | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV60334808; called by muse, mutect2, varscan2
- MADD | c.2318T>G p.F773C | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.479); catalogued as COSV60621867; called by muse, mutect2, varscan2
- MAGED2 | c.1372A>G p.K458E | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV54497199, COSV54497259; called by muse, varscan2
- MAGEF1 | c.671T>G p.L224R | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58633553; called by muse, mutect2, varscan2
- MBNL2 | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59119102; called by muse, mutect2, varscan2
- MCCC1 | c.1582C>T p.L528F | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV55607412; called by muse, mutect2, varscan2
- MYH3 | c.4318G>T p.A1440S | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV56862578, COSV56866239; called by muse, mutect2, varscan2
- MYO5A | c.5021T>A p.V1674D | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs918808525, COSV62558192; called by muse, mutect2
- MYORG | c.1775C>A p.P592Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99898812; called by muse, mutect2, varscan2
- NFIX | c.558G>A p.P186= | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as rs1180613035, COSV100666621; called by muse, mutect2
- NIN | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55384252; called by muse, mutect2, varscan2
- NKX3-1 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.341); catalogued as COSV66511846, COSV66511974; called by muse, mutect2, varscan2
- NOXRED1 | c.809A>T p.H270L | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100033208; called by muse, mutect2, varscan2
- OBSL1 | c.4307C>T p.T1436M | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as rs1050861317, COSV54704407; called by muse, mutect2, varscan2
- OCLN | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.695); catalogued as COSV62285041; called by muse, mutect2, varscan2
- OR6C3 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.089); catalogued as COSV65570792; called by muse, mutect2, varscan2
- OR6C6 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV64455584; called by muse, mutect2, varscan2
- OR6M1 | c.109G>C p.A37P | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV58433068; called by muse, mutect2, varscan2
- PDCD7 | c.1224G>C p.E408D | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV52600018; called by muse, mutect2, varscan2
- PKHD1 | c.11066T>A p.L3689* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV64384121; called by muse, mutect2, varscan2
- PLXNA3 | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63753534; called by muse, mutect2, varscan2
- PLXNB2 | c.5427G>C p.L1809F | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63780656; called by muse, mutect2, varscan2
- PMFBP1 | c.576C>G p.I192M | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV52821860, COSV52831807; called by muse, mutect2, varscan2
- PPM1L | c.1045G>T p.V349L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV55562072; called by muse, mutect2, varscan2
- PTPRT | c.1391T>A p.L464Q | Missense Mutation (SNP) | VAF 88/170 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61969086; called by muse, mutect2, varscan2
- RBM15 | c.2839T>A p.Y947N | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV63923266; called by muse, mutect2, varscan2
- RBSN | c.1833A>T p.L611F | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs905821751, COSV53792000; called by muse, mutect2, varscan2
- RFX5 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51838392; called by muse, mutect2, varscan2
- RHPN1 | c.860G>A p.C287Y | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56645525; called by muse, mutect2, varscan2
- RO60 | c.1327G>A p.G443S | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs781750738, COSV66473383; called by muse, mutect2, varscan2
- SERPINA11 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58241402; called by muse, mutect2, varscan2
- SETDB1 | c.1576T>C p.Y526H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1311530032, COSV54979167; called by muse, mutect2, varscan2
- SLC35G6 | c.360T>A p.S120R | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV100263714; called by muse, mutect2, varscan2
- SLC4A2 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100055730; called by muse, mutect2, varscan2
- SOX5 | c.1011A>T p.Q337H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201582044, COSV100507969; called by muse, mutect2, varscan2
- SPAG17 | c.3645G>C p.E1215D | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as COSV60455293; called by muse, mutect2, varscan2
- SUCNR1 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV62911985; called by muse, mutect2, varscan2
- SYN2 | c.988T>A p.S330T | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV101413889; called by muse, mutect2, varscan2
- TECTA | c.1057T>G p.L353V | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV50693896; called by muse, mutect2, varscan2
- TENT5D | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 133/260 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.502); catalogued as rs767337141, COSV100382521, COSV57635749; called by muse, mutect2, varscan2
- THBS2 | c.976T>G p.F326V | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV64677784; called by muse, mutect2, varscan2
- THOC2 | c.4601A>T p.K1534I | Missense Mutation (SNP) | VAF 99/352 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as COSV55542683; called by muse, mutect2, varscan2
- TLR8 | c.2862G>C p.W954C (on ENST00000218032 / NM_138636.5; = p.W972C on NM_016610.4) | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV54316962, COSV54321095, COSV99487088; called by muse, mutect2, varscan2
- TMEM108 | c.82G>C p.A28P | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV58866729; called by muse, mutect2, varscan2
- TMEM168 | c.511A>G p.T171A | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV57179969; called by muse, mutect2, varscan2
- TNFSF14 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV55590137; called by muse, varscan2
- TSC2 | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs45437797, CM114749; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSPAN9 | c.27G>C p.L9F | Missense Mutation (SNP) | VAF 530/1448 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.278); catalogued as COSV50722611; called by muse, varscan2
- TTC23 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV50441050; called by muse, mutect2, varscan2
- TTN | c.5115C>G p.F1705L (on ENST00000591111; = p.F1659L on NM_003319.4) | Missense Mutation (SNP) | VAF 61/318 reads (19%) | PolyPhen probably damaging (0.987); catalogued as rs375828531; called by muse, mutect2, varscan2
- UBLCP1 | c.173A>G p.D58G | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99707432; called by muse, mutect2, varscan2
- WDR55 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100845594, COSV64225654; called by muse, mutect2, varscan2
- ZNF285 | c.1732C>G p.L578V | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV100450123; called by muse, mutect2, varscan2
- FAM13B | c.2346del p.F782Lfs*18 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- IGBP1P2 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 87/232 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ZFP36L2 | c.617_618dup p.P207Afs*255 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | called by mutect2, pindel
- ABCC11 | c.1932G>T p.L644= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV62321972; called by muse, mutect2, varscan2
- ACTN4 | c.603G>C p.L201= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as rs1218562487, COSV53144226, COSV53146603; called by muse, mutect2, varscan2
- ADAMTSL1 | c.27T>A p.P9= | Silent (SNP) | VAF 63/144 reads (44%) | catalogued as COSV52811168; called by muse, mutect2, varscan2
- ATP1A3 | c.1506C>T p.N502= (on ENST00000545399 / NM_001256214.2; = p.N489= on NM_152296.5) | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as rs138797500; called by muse, mutect2, varscan2
- CDC16 | c.618G>A p.E206= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as rs1462495443, COSV52958712, COSV52960224; called by muse, mutect2, varscan2
- EPHA6 | c.483T>C p.N161= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV67564727; called by muse, mutect2, varscan2
- EPS8L2 | c.279G>C p.L93= | Silent (SNP) | VAF 56/142 reads (39%) | catalogued as COSV59347301; called by muse, mutect2, varscan2
- FAM163B | c.174G>A p.L58= | Silent (SNP) | VAF 47/195 reads (24%) | catalogued as rs1160015848; called by muse, mutect2, varscan2
- FAM47A | c.204T>A p.T68= | Silent (SNP) | VAF 14/317 reads (4%) | catalogued as COSV100650049; called by muse, mutect2
- FOXD4L4 | c.52C>A p.R18= | Silent (SNP) | VAF 41/338 reads (12%) | called by mutect2, varscan2
- FOXD4L5 | c.52C>A p.R18= | Silent (SNP) | VAF 25/134 reads (19%) | catalogued as COSV101073260; called by muse, mutect2, varscan2
- GOLGB1 | c.8661A>G p.Q2887= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100511456; called by muse, mutect2, varscan2
- INO80D | c.2013T>A p.I671= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV68958439; called by muse, mutect2, varscan2
- MRPS34 | c.480C>T p.S160= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV51599528; called by muse, mutect2, varscan2
- MYO3A | c.2739T>C p.R913= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as COSV56323868; called by muse, mutect2, varscan2
- PCDHB2 | c.1299G>A p.L433= | Silent (SNP) | VAF 62/195 reads (32%) | catalogued as COSV99166454; called by muse, mutect2, varscan2
- RAD52 | c.891G>A p.T297= | Silent (SNP) | VAF 34/498 reads (7%) | catalogued as rs373796726; called by muse, mutect2
- RIPOR3 | c.819G>A p.L273= | Silent (SNP) | VAF 63/105 reads (60%) | catalogued as COSV50386630; called by muse, mutect2, varscan2
- SACS | c.486G>A p.A162= | Silent (SNP) | VAF 47/77 reads (61%) | catalogued as rs775081172, COSV66536802; called by muse, mutect2, varscan2
- SPATS2L | c.189A>T p.G63= | Silent (SNP) | VAF 73/186 reads (39%) | catalogued as COSV62346507; called by muse, mutect2, varscan2
- TAF1 | c.441G>A p.K147= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as COSV52109550; called by muse, mutect2, varscan2
- TMEM187 | c.114G>A p.E38= | Silent (SNP) | VAF 87/256 reads (34%) | catalogued as COSV100890188; called by muse, mutect2, varscan2
- TSSK1B | c.78A>G p.V26= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV66815068; called by muse, mutect2, varscan2
- TUBGCP6 | c.5271G>T p.G1757= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV50539277; called by muse, mutect2, varscan2
- ZFAND2B | c.99C>T p.C33= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV54694160; called by muse, mutect2
- ZNF536 | c.969C>T p.H323= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs1157887399, COSV62821032; called by muse, mutect2, varscan2
- C1orf220 | n.538C>T | RNA (SNP) | VAF 33/81 reads (41%) | catalogued as rs376810333; called by muse, mutect2, varscan2
- POR | c.*230G>C | 3'UTR (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100115738, COSV58693690; called by muse, mutect2
- RN7SL484P | chr15:99792523 G>A | 3'Flank (SNP) | VAF 6/17 reads (35%) | catalogued as rs755780354; called by muse, mutect2, varscan2
